TCGA case TCGA-W3-AA1V — Skin Cutaneous Melanoma (TCGA-SKCM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Nevi and Melanomas; Primary site: Lymph nodes; Tissue source site: John Wayne Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9817ec15-605a-40db-b848-2199e5ccbb7b

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 63 years; Vital status: Dead; Days to death: 1,280 days (3.5 years).

Diagnoses (6)
1. Malignant melanoma, NOS (the primary disease): ICD-O-3 morphology code: 8720/3; ICD-10 code: C77.3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Lymph nodes of axilla or arm; Classification of tumor: Progression; Age at diagnosis: 66.4 years (24,260 days); Days to diagnosis: 946 days (2.6 years); Prior treatment: No.
   Recorded as not given: Pharmaceutical Therapy, NOS, prior to procurement; Radiation Therapy, NOS, prior to procurement.
2. Malignant melanoma, NOS: Tissue or organ of origin: Skin, NOS; Classification of tumor: primary; Clark level: IV; Sites of involvement: Skin, Trunk; Ulceration indicator: No.
   Pathology details: Breslow thickness category: >1.0-2.0 mm.
   Recorded as not given: Radiation Therapy, NOS.
3. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 63.8 years (23,314 days); Year of diagnosis: 1994; AJCC staging edition: 4th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Melanoma known primary: Yes.
   Pathology details: Consistent pathology review: Yes.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Antineoplastic Vaccine; Days to treatment start: 1,005 days (2.8 years); Days to treatment end: 1,280 days (3.5 years); Treatment outcome: Progressive Disease; Clinical trial indicator: Yes.
   Recorded as not given: adjuvant Radiation Therapy, NOS.
4. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Liver. Age at diagnosis: 67.2 years (24,533 days); Days to diagnosis: 1,219 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,219 days (3.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
5. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Kidney, NOS. Age at diagnosis: 67.2 years (24,533 days); Days to diagnosis: 1,219 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,219 days (3.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.
6. Metastasis of diagnosis 3 (Malignant melanoma, NOS), site: Adrenal gland, NOS. Age at diagnosis: 67.2 years (24,533 days); Days to diagnosis: 1,219 days (3.3 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Progressive Disease; Days to treatment start: 1,219 days (3.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 1,219 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Kidney, NOS; Days to progression: 1,219 days (3.3 years).
- Day 1,219 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Adrenal gland, NOS; Days to progression: 1,219 days (3.3 years).
- Day 1,219 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 1,219 days (3.3 years).
- Days to follow up: 1,280 days (3.5 years); Disease response: With Tumor.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 91 kg; Height: 180 cm; BMI: 28.1.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-W3-AA1V-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-W3-AA1V-06B: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-W3-AA1V-06B-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 2; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-W3-AA1V-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor; Breslow thickness at diagnosis: 1.3; Primary melanoma tumor ulceration: No; Radiation therapy to primary: No; Primary location: Regional Lymph Node; Primary melanoma skin type: Non-glabrous skin; Prior radiation therapy: No; History neoadjuvant treatment: No.
- Sites of primary melanomas: Primary multiple at diagnosis: No.
- Sites of primary melanomas, Site: Submitted tumor site: Other  Specify; Melanoma primary count: 1; Site of primary tumor other: Back.
- Drug treatment: Clinical trial drug classification: Vaccine; Treatment best response: Clinical Progressive Disease.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,280 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,280 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,219 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-W3-AA1V-06B-11D-A400-01): tumor purity 0.73, ploidy 2.7, whole-genome doublings 1.
